Somatic mutation profile of tumor specimen MP2PRT-PARBEE-TMP1-A (aliquot MP2PRT-PARBEE-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARBEE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (585 days).
Specimen MP2PRT-PARBEE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76f718b4-d3d8-464a-9a5d-3065a15f6f20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARBEE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARBEE-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76952995-37c4-4dd5-b4da-d75e0fcba55f

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Del 1, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HHIPL1 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1179090437; called by muse, mutect2, varscan2
- KALRN | c.4471C>T p.R1491W | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781157532, COSV99567757; called by muse, mutect2, varscan2
- FLT3 | c.1762_1771delinsA p.E588_Y591delinsN | In Frame Del (DEL) | VAF 82/235 reads (35%) | called by pindel, varscan2*
- MFNG | c.803T>A p.L268H | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MLIP | c.25del p.R9Efs*4 | Frame Shift Del (DEL) | VAF 70/268 reads (26%) | called by mutect2, pindel, varscan2
- SETD4 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 91/435 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF442 | c.1446C>A p.H482Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- PTPRS | c.4146G>A p.T1382= | Silent (SNP) | VAF 180/400 reads (45%) | catalogued as rs777445829; called by muse, mutect2, varscan2
